CCDI case PBCMWC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d92663df-1e8b-406a-a76e-264d7a10a72e

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 6.5 years (2,388 days).

Biospecimens (2 samples)
- Sample 0DW2VL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW2W6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
